Somatic mutation profile of tumor specimen TCGA-HT-7880-01A (aliquot TCGA-HT-7880-01A-11D-2395-08) from TCGA case TCGA-HT-7880, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.2 years (11,043 days).
Specimen TCGA-HT-7880-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28a7a97a-b46f-41a6-950b-10637cdc4644.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7880-10A (Blood Derived Normal), aliquot TCGA-HT-7880-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9710d75b-e547-4931-a0fe-4f0ed890abb8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.3739_3742del p.F1247Ifs*18 | Frame Shift Del (DEL) | VAF 24/238 reads (10%) | catalogued as rs1064794276; ClinVar: pathogenic; called by mutect2, pindel
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 10/95 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF2 | c.1873A>G p.T625A | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.113); catalogued as COSV53974603; called by muse, mutect2, varscan2
- ATRX | c.2848A>T p.K950* | Nonsense Mutation (SNP) | VAF 18/96 reads (19%) | catalogued as COSV64870583; called by muse, mutect2, varscan2
- PTPN14 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs776055399, COSV65281112, COSV65289088; called by muse, mutect2
- SPOCK2 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV58034920; called by muse, mutect2
- ATRX | c.1960C>A p.R654= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV64870592, COSV64871923; called by muse, mutect2, varscan2
- PKN3 | c.1197G>C p.L399= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV52574673; called by muse, mutect2
